Somatic mutation profile of tumor specimen TCGA-GN-A265-06A (aliquot TCGA-GN-A265-06A-21D-A197-08) from TCGA case TCGA-GN-A265, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.0 years (19,712 days).
Specimen TCGA-GN-A265-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d1beea5-395a-46c0-adf5-272cdf16b3c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A265-10A (Blood Derived Normal), aliquot TCGA-GN-A265-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6762846a-e369-4bfa-8510-2332102bde5a

The open-access MAF lists 230 somatic variants for this specimen: 164 protein-altering or splice-affecting, 62 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 62, Nonsense Mutation 8, Splice Site 4, 3'UTR 2, Splice Region 2, Intron 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AADACL4 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66106883; called by muse, mutect2
- ABCA10 | c.4541T>G p.L1514* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV52227311; called by muse, mutect2, varscan2
- ABCB5 | c.2813G>A p.R938Q (on ENST00000404938 / NM_001163941.2; = p.R493Q on NM_178559.6) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs765330792, COSV51708937, COSV51714265, COSV99328970; called by mutect2, varscan2
- ABCD2 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV58053827; called by mutect2, varscan2
- ACOT12 | c.1104G>A p.W368* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as COSV56896885; called by muse, mutect2, varscan2
- ACTC1 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.987); catalogued as CM086759, COSV51759217; called by muse, mutect2, varscan2
- ADCY8 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV53898884; called by muse, mutect2, varscan2
- AHI1 | c.2988A>G p.K996= | Splice Region (SNP) | VAF 8/51 reads (16%) | catalogued as COSV55632750; called by muse, mutect2, varscan2
- AKR1D1 | c.819A>C p.K273N | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV54339463; called by muse, mutect2, varscan2
- AMPH | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57734569; called by muse, mutect2
- ANK3 | c.6676G>A p.E2226K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as COSV55058908; called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5900C>T p.P1967L | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV51854763; called by muse, mutect2, varscan2
- ANTXR1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs141240644; called by mutect2, varscan2
- APOB | c.11915G>A p.G3972E | Missense Mutation (SNP) | VAF 47/434 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV51946074; called by muse, varscan2
- APOB | c.6235G>A p.E2079K | Missense Mutation (SNP) | VAF 64/724 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as COSV51946085; called by muse, mutect2
- ARHGAP26 | c.1656T>G p.F552L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99188621; called by muse, mutect2, varscan2
- ARHGAP26 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as COSV99188628; called by mutect2, varscan2
- ARHGEF19 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV54616348; called by muse, mutect2, varscan2
- BCAT1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1471498583, COSV53915599; called by muse, mutect2
- CASC3 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV52868691; called by muse, mutect2, varscan2
- CCDC85A | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68154229; called by muse, mutect2, varscan2
- CIITA | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs746605931, COSV60860443; called by mutect2, varscan2
- CNDP1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184229875, COSV100722136; called by muse, mutect2, varscan2
- CNST | c.1093T>C p.C365R | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63622236; called by muse, mutect2, varscan2
- COL19A1 | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as COSV59581821; called by mutect2, varscan2
- COL1A1 | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99866071; called by muse, mutect2, varscan2
- CPT1C | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV54921224; called by muse, mutect2, varscan2
- CS | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV60834268; called by muse, mutect2, varscan2
- CSF2RB | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53259897; called by muse, mutect2, varscan2
- CSNK1A1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV55793508, COSV55798296; called by muse, mutect2, varscan2
- CTNNA3 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs770925969, COSV57721130; called by muse, mutect2, varscan2
- DCAF1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.361); catalogued as rs782390664, COSV60045488; called by muse, mutect2, varscan2
- DGKB | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.971); catalogued as COSV51807264; called by muse, mutect2, varscan2
- DHFR | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1307188069, COSV71485675; called by mutect2, varscan2
- DLEC1 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV57304233; called by muse, mutect2
- DMAC2 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99700378; called by muse, mutect2, varscan2
- DMAC2 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782625556, COSV99700379; called by muse, mutect2, varscan2
- DMWD | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52180830; called by muse, mutect2, varscan2
- DNAH11 | c.6520G>A p.G2174R | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60971361; called by muse, mutect2, varscan2
- DNTT | c.1005G>A p.R335= | Splice Region (SNP) | VAF 16/179 reads (9%) | catalogued as COSV64522597, COSV64523492; called by muse, mutect2
- DPP10 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100056259, COSV99059673; called by muse, mutect2, varscan2
- DYSF | c.5956G>A p.E1986K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50268836; called by mutect2, varscan2
- ELN | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52713462; called by muse, mutect2, varscan2
- EPG5 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs1204559552, COSV56353762; called by muse, varscan2
- ERLEC1 | c.1301T>A p.L434Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51753016; called by mutect2, varscan2
- F13A1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV53552757, COSV53564237; called by muse, mutect2, varscan2
- FAM160A2 | c.2498A>G p.K833R (on ENST00000449352 / NM_001098794.2; = p.K847R on NM_032127.4) | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.17); catalogued as COSV56413555; called by muse, mutect2, varscan2
- FAM222A | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV62723813; called by muse, mutect2, varscan2
- FAM71C | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.264); catalogued as COSV60944055; called by muse, mutect2, varscan2
- FAT4 | c.9802C>T p.L3268F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58700765; called by mutect2, varscan2
- FGD2 | c.752G>C p.R251P | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51465329; called by muse, mutect2, varscan2
- FGFR2 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs765174665, COSV60655179; called by mutect2, varscan2
- FOXA3 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs202014979, COSV56217115; called by muse, mutect2, varscan2
- GLIS1 | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100391043, COSV56553690; called by muse, mutect2, varscan2
- GOT1 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV65147696; called by muse, mutect2
- GRB14 | c.796T>G p.S266A | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55741359; called by muse, mutect2, varscan2
- GRM1 | c.2155A>G p.T719A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.052); catalogued as COSV51147692, COSV99266647; called by muse, mutect2, varscan2
- GRXCR1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754691699, COSV67670250; called by mutect2, varscan2
- HCLS1 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287193667, COSV58858925; called by muse, mutect2
- IDO1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV53715613; called by muse, mutect2, varscan2
- IGHV1-46 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1555524836; called by muse, mutect2, varscan2
- IGKV3-7 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as rs1290893636; called by muse, mutect2, varscan2
- IQCG | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV54564555; called by muse, varscan2
- IREB2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV51925269; called by muse, mutect2, varscan2
- ITGA2B | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52232568; called by muse, mutect2
- JAG1 | c.671G>A p.W224* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as COSV54754569; called by muse, varscan2
- KCNH1 | c.2453G>A p.G818E (on ENST00000271751 / NM_172362.3; = p.G791E on NM_002238.4) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs747517591, COSV55094941; called by muse, mutect2, varscan2
- KCNJ3 | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54530638; called by muse, mutect2, varscan2
- KCTD8 | c.1200G>A p.W400* | Nonsense Mutation (SNP) | VAF 40/237 reads (17%) | catalogued as COSV63593626; called by muse, mutect2, varscan2
- KIAA1958 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61726497; called by muse, mutect2, varscan2
- KRTAP10-4 | c.828C>A p.C276* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100551260; called by mutect2, varscan2
- KRTAP10-4 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV100551261; called by muse, mutect2, varscan2
- KSR2 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.188); catalogued as rs920071051, COSV56679724; called by muse, mutect2, varscan2
- LNPK | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.304); catalogued as COSV55825527; called by muse, mutect2
- LRP2 | c.12320G>A p.G4107E | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs1479138919, COSV55562165; called by muse, mutect2, varscan2
- LRRC66 | c.143T>C p.F48S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.946); catalogued as COSV58635799; called by muse, mutect2, varscan2
- MAST1 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52251828; called by muse, mutect2, varscan2
- MUC16 | c.39073G>A p.G13025R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.052); catalogued as COSV101197302, COSV101200360; called by muse, varscan2
- MYH1 | c.3403A>G p.K1135E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV56854132; called by muse, mutect2, varscan2
- MYH15 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV56319856, COSV99843346; called by muse, mutect2
- MYO1H | c.2831C>G p.S944C | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57327915; called by muse, mutect2
- NEBL | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 23/267 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV65804869; called by muse, mutect2
- NEO1 | c.1565G>C p.G522A | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV56076164; called by muse, varscan2
- NFASC | c.91C>T p.P31S (on ENST00000339876 / NM_001378329.1; = p.L31= on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs375813060; called by mutect2, varscan2
- NLGN2 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57211404; called by mutect2, varscan2
- OR10X1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100936633, COSV63766869; called by mutect2, varscan2
- OR2A5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs149614119, COSV68738535; called by mutect2, varscan2
- OR4A15 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59036704; called by muse, mutect2, varscan2
- OR51L1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV58625352; called by muse, mutect2, varscan2
- PAK5 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs562732119, COSV62020766; called by mutect2, varscan2
- PCDHA4 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); catalogued as COSV63544582; called by muse, mutect2, varscan2
- PCDHAC1 | c.2082A>T p.L694F | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV53863046; called by mutect2, varscan2
- PCDHB14 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs1276148574, COSV53387816; called by muse, mutect2, varscan2
- PCDHGA2 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV54001642; called by muse, varscan2
- PCDHGA3 | c.1465T>C p.Y489H | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54001652; called by muse, mutect2
- PCLO | c.7772C>T p.T2591I | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61655309; called by muse, mutect2
- PEG3 | c.4060C>T p.H1354Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV55630328; called by mutect2, varscan2
- PKDREJ | c.5354C>T p.S1785L | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.87); catalogued as COSV53551684; called by muse, mutect2, varscan2
- PLCB1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755135706, COSV62045657, COSV62062024; called by mutect2, varscan2
- PLCL1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV70839999; called by muse, mutect2, varscan2
- PLXDC2 | c.1454C>A p.A485D | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65907123; called by muse, mutect2
- PLXNA1 | c.3880C>T p.L1294F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99302017; called by muse, varscan2
- POSTN | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV65714013; called by muse, mutect2
- PPA2 | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58997442; called by muse, mutect2, varscan2
- PPP4R1 | c.1307C>A p.P436Q (on ENST00000400556 / NM_001042388.3; = p.P419Q on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV53283632; called by mutect2, varscan2
- PRDM1 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV64845863; called by muse, mutect2, varscan2
- PRDM9 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57002306, COSV57004214; called by muse, mutect2, varscan2
- PRRT2 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV99569120; called by muse, mutect2, varscan2
- PSG8 | c.710-1G>A p.X237_splice | Splice Site (SNP) | VAF 42/244 reads (17%) | catalogued as rs747573382, COSV60614131; called by muse, mutect2, varscan2
- PTCD2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV57338729; called by muse, mutect2, varscan2
- PXDNL | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as rs1468770466, COSV62494876; called by muse, mutect2, varscan2
- RAD50 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV99528418; called by muse, mutect2, varscan2
- RBM12 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.068); catalogued as COSV58291727, COSV58293773; called by muse, varscan2
- RBM48 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56003391; called by muse, mutect2, varscan2
- RGS7 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.758); catalogued as rs202033477, COSV58554179; called by muse, mutect2, varscan2
- RNF6 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100644602, COSV60419982; called by muse, mutect2, varscan2
- RP1 | c.1323A>C p.Q441H | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV55123139; called by muse, mutect2, varscan2
- RPS6KL1 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1394961431, COSV63581632; called by muse, mutect2, varscan2
- RXFP2 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs867037646, COSV53638767; called by muse, mutect2, varscan2
- RYR2 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.903); catalogued as COSV63703638; called by muse, mutect2, varscan2
- SCNN1G | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as COSV55600905; called by muse, mutect2, varscan2
- SEMG1 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV54873614; called by muse, varscan2
- SIGLEC6 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV100585614, COSV58436228; called by muse, mutect2
- SLC10A2 | c.1013A>G p.K338R | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1195472716, COSV55360837; called by muse, mutect2, varscan2
- SLC12A5 | c.994G>A p.G332R (on ENST00000454036 / NM_001134771.2; = p.G309R on NM_020708.5) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV54788436; called by muse, mutect2, varscan2
- SLC2A10 | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100826321; called by muse, mutect2
- SLC49A3 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV59141314; called by muse, mutect2, varscan2
- SMARCA5 | c.977A>G p.E326G | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV51646373; called by muse, mutect2
- SMCHD1 | c.3685C>T p.P1229S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs1391113980, COSV55260339; called by muse, mutect2, varscan2
- SMOX | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV53867006; called by muse, mutect2, varscan2
- SOAT1 | c.565T>C p.W189R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV62656072; called by muse, mutect2, varscan2
- SORCS3 | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs563904095, COSV63819388; called by mutect2, varscan2
- SPEM1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV57211407; called by muse, mutect2, varscan2
- SULT1B1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV60208816; called by muse, mutect2
- SYNE1 | c.23460+1G>A p.X7820_splice (on ENST00000367255 / NM_182961.4; = p.X7749_splice on NM_033071.3) | Splice Site (SNP) | VAF 11/73 reads (15%) | catalogued as COSV55057122; called by muse, mutect2, varscan2
- TCIRG1 | c.1788G>A p.W596* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV55836917; called by muse, mutect2, varscan2
- THSD7B | c.1034G>T p.W345L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55699274; called by mutect2, varscan2
- TLR4 | c.2459C>T p.S820L (on ENST00000355622 / NM_138554.5; = p.S780L on NM_003266.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62923316; called by mutect2, varscan2
- TMC2 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.893); catalogued as COSV62656558; called by muse, mutect2, varscan2
- TNFSF15 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs150498686; called by mutect2, varscan2
- TOX2 | c.1459C>T p.L487F (on ENST00000358131 / NM_001098798.2; = p.L463F on NM_032883.3) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57892319; called by muse, mutect2, varscan2
- TRIM15 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.197); catalogued as COSV64990133; called by muse, varscan2
- TRIM22 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as rs756008298, COSV66091434; called by muse, mutect2, varscan2
- TRIOBP | c.2375G>A p.R792K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV60380118, COSV60382040; called by muse, mutect2, varscan2
- TTN | c.56090G>A p.G18697E (on ENST00000591111; = p.G11273E on NM_003319.4) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | PolyPhen probably damaging (1); catalogued as COSV60240299; called by muse, mutect2, varscan2
- TUBA1C | c.1220G>A p.W407* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as COSV99988587; called by muse, mutect2, varscan2
- TUT4 | c.4676C>T p.S1559F | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV57117966; called by muse, varscan2
- USP24 | c.3881C>T p.S1294F | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV53774702; called by muse, mutect2, varscan2
- VANGL2 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1348283097, COSV63604106; called by muse, mutect2, varscan2
- VPS13D | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV50663900; called by muse, mutect2, varscan2
- XKR9 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.777); catalogued as COSV101281792; called by muse, mutect2, varscan2
- ZC3H3 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV52793166; called by muse, mutect2, varscan2
- ZDBF2 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV65622169, COSV65625388; called by muse, mutect2, varscan2
- ZMYM6 | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.727); catalogued as rs774508184, COSV64121039; called by mutect2, varscan2
- ZNF532 | c.3346C>T p.P1116S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs936918525, COSV60174770; called by muse, mutect2, varscan2
- ZNF646 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.741); catalogued as COSV56217528; called by muse, mutect2, varscan2
- ZSCAN22 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs774236250, COSV61639478; called by muse, mutect2, varscan2
- ZSWIM2 | c.1639G>A p.G547S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV54577951; called by muse, mutect2, varscan2
- B2M | c.230_247del p.S77_Y83delinsN | In Frame Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- CSNK1D | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MCTP1 | c.838+1G>T p.X280_splice | Splice Site (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- POTEA | c.1387G>A p.D463N (on ENST00000519951 / NM_001005365.2; = p.D417N on NM_001002920.1) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TAP2 | c.1795_1795+5del p.X599_splice | Splice Site (DEL) | VAF 20/162 reads (12%) | called by mutect2, pindel, varscan2
- ALLC | c.618C>T p.V206= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs765099313, COSV52997201; called by mutect2, varscan2
- AMY2A | c.405C>T p.N135= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101340609; called by mutect2, varscan2
- AP3D1 | c.2307C>T p.A769= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV61431413; called by muse, mutect2, varscan2
- ASXL3 | c.5298G>A p.Q1766= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs780762296, COSV52474536; called by muse, mutect2, varscan2
- AVPR1B | c.636G>A p.V212= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV65638466; called by mutect2, varscan2
- CACNG2 | c.888C>T p.F296= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV55638891; called by muse, mutect2, varscan2
- CCRL2 | c.741C>T p.F247= | Silent (SNP) | VAF 30/400 reads (8%) | catalogued as rs764672393, COSV62193521; called by muse, mutect2
- CDRT1 | c.328T>C p.L110= | Silent (SNP) | VAF 15/198 reads (8%) | catalogued as COSV55414249; called by muse, mutect2
- COL1A1 | c.3834C>T p.P1278= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs1299931242, COSV99866066; called by mutect2, varscan2
- CPEB1 | c.1345C>T p.L449= (on ENST00000617958; = p.L384= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs1305515428, COSV55620599; called by muse, mutect2, varscan2
- CYP2C19 | c.126C>T p.I42= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV64907502; called by muse, mutect2, varscan2
- DENND2A | c.837G>A p.G279= | Silent (SNP) | VAF 48/203 reads (24%) | catalogued as rs774695285, COSV52056272; called by muse, mutect2, varscan2
- ENPP7 | c.750G>A p.T250= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs782072491, COSV60387437; called by mutect2, varscan2
- FOLH1 | c.1120C>T p.L374= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as COSV57054131; called by muse, mutect2, varscan2
- GDF5 | c.1161C>T p.R387= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as COSV100976666; called by muse, mutect2
- GPATCH3 | c.1434C>T p.S478= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV64652484; called by mutect2, varscan2
- IP6K1 | c.183C>T p.S61= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV58664679; called by muse, varscan2
- KIR3DL3 | c.645C>T p.I215= | Silent (SNP) | VAF 30/234 reads (13%) | catalogued as rs751569195, COSV52547929; called by mutect2, varscan2
- LMX1A | c.1122C>T p.S374= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV54225558; called by muse, mutect2, varscan2
- LRFN3 | c.1641C>T p.I547= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55818647; called by mutect2, varscan2
- LRFN5 | c.1179T>A p.G393= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV53269183; called by muse, mutect2, varscan2
- MAGEC2 | c.897C>T p.F299= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV55998040; called by muse, mutect2, varscan2
- MFSD4A | c.772C>T p.L258= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV65656876; called by muse, mutect2, varscan2
- MYH15 | c.5343G>A p.L1781= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as COSV56316171; called by mutect2, varscan2
- MYH15 | c.2280C>T p.S760= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as COSV56319489; called by muse, mutect2
- NCAPD3 | c.957C>T p.A319= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV73258549; called by muse, mutect2, varscan2
- NIPBL | c.3027T>C p.S1009= | Silent (SNP) | VAF 47/329 reads (14%) | catalogued as COSV56960844; called by muse, mutect2, varscan2
- NLRP13 | c.612C>T p.I204= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as rs142264094; called by muse, mutect2, varscan2
- OR4S1 | c.543C>T p.P181= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs1188930894, COSV60679652; called by muse, mutect2, varscan2
- OTOA | c.1681C>T p.L561= (on ENST00000286149; = p.L547= on NM_144672.4) | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as rs1465327056, COSV53760874, COSV53763229; called by muse, mutect2
- PASD1 | c.1860G>A p.Q620= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs755004199, COSV64856870; called by mutect2, varscan2
- PCDHA10 | c.129C>T p.F43= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV56532265; called by mutect2, varscan2
- PCDHB7 | c.1680C>T p.F560= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs199671683, COSV50769132; called by mutect2, varscan2
- PER2 | c.621C>T p.I207= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV54526246; called by muse, mutect2, varscan2
- PHLPP2 | c.1918C>T p.L640= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs375738138; called by muse, mutect2, varscan2
- PKD1 | c.8409C>T p.G2803= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV51922118; called by muse, mutect2, varscan2
- PLEKHA5 | c.630C>T p.I210= | Silent (SNP) | VAF 31/225 reads (14%) | catalogued as rs1249882913, COSV54708604; called by muse, mutect2, varscan2
- PLEKHH2 | c.2439C>T p.T813= | Silent (SNP) | VAF 33/275 reads (12%) | catalogued as rs1183646026, COSV56758429, COSV56758471; called by muse, mutect2, varscan2
- POTEA | c.1386G>A p.Q462= (on ENST00000519951 / NM_001005365.2; = p.Q416= on NM_001002920.1) | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- PRDM2 | c.681C>T p.L227= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV52452362; called by muse, mutect2, varscan2
- PREX1 | c.1746G>A p.E582= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV64255116; called by muse, mutect2, varscan2
- PRMT2 | c.177C>T p.I59= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs1199661935, COSV52454277; called by muse, mutect2, varscan2
- PXDNL | c.3498G>A p.K1166= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs760931614, COSV62492396; called by mutect2, varscan2
- RBBP8NL | c.1287G>A p.E429= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV53350242; called by muse, mutect2
- RDM1 | c.459G>A p.P153= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs373207074; called by mutect2, varscan2
- SELENON | c.531C>T p.F177= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs758506235, COSV62525694; called by mutect2, varscan2
- SHISA5 | c.525G>A p.Q175= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV56497730; called by muse, varscan2
- SLC24A3 | c.555C>T p.G185= | Silent (SNP) | VAF 42/232 reads (18%) | catalogued as COSV60127515; called by muse, varscan2
- SLC6A13 | c.813G>A p.T271= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs147679992, COSV58259322; called by mutect2, varscan2
- SLC6A14 | c.669C>T p.L223= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV64148047; called by muse, mutect2, varscan2
- SPTBN1 | c.5160C>T p.V1720= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs368730014; called by mutect2, varscan2
- STAG2 | c.2100C>T p.A700= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV54367885; called by mutect2, varscan2
- SYNE1 | c.10041C>T p.V3347= (on ENST00000367255 / NM_182961.4; = p.V3354= on NM_033071.3) | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs1480193161, COSV55057155; called by muse, mutect2, varscan2
- TBX2 | c.1815C>T p.S605= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53600414; called by muse, mutect2, varscan2
- TRPC5 | c.2373G>A p.R791= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV53299016; called by muse, mutect2, varscan2
- TTLL7 | c.585C>T p.F195= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV53087425; called by muse, mutect2, varscan2
- TTN | c.25959G>A p.R8653= (on ENST00000591111; = p.R7726= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV59995059; called by muse, mutect2, varscan2
- TULP4 | c.2802C>T p.V934= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs756568666, COSV65579048; called by mutect2, varscan2
- VIP | c.261C>T p.T87= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV65889276, COSV65889391; called by muse, mutect2, varscan2
- VPS13D | c.4476C>T p.T1492= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV50663946; called by muse, mutect2, varscan2
- ZFPM2 | c.1275G>A p.K425= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs773287088, COSV65875088; called by mutect2, varscan2
- ZNFX1 | c.4983G>A p.Q1661= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs765141163, COSV65594210, COSV65600416; called by muse, mutect2, varscan2
- B4GALNT1 | c.*2878G>A | 3'UTR (SNP) | VAF 12/170 reads (7%) | catalogued as COSV57544165; called by muse, mutect2
- EGFR | c.1881-863G>A | Intron (SNP) | VAF 10/69 reads (14%) | catalogued as rs371814116, COSV99285452; called by mutect2, varscan2
- HK3 | c.*2G>A | 3'UTR (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99457521; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579089 G>A | 5'Flank (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
